Gene-level copy-number profile of tumor specimen TCGA-HB-A2OT-01A from TCGA case TCGA-HB-A2OT, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 78.4 years (28,632 days).
Specimen TCGA-HB-A2OT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.77f0f727-a5c8-4233-bb05-e645fe298d49.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HB-A2OT-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cfeaef80-db95-4ffe-8850-3ef5eb50340d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 16,233; copy number 2: 29,922; copy number 3: 12,344; copy number 4: 202; copy number 5: 835; copy number 7: 264.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HB-A2OT-01A-11D-A21P-01): tumor purity 0.46, ploidy 1.71, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:3,824,127–4,348,392, 4 genes (within-gene range 0–1): GLIS3, AL137071.1, GLIS3-AS1, AL359095.1.
- chr13:48,488,963–48,976,867, 8 genes: RCBTB2, AL157813.2, AL157813.1, LINC01077, LINC00462, CYSLTR2, PSME2P2, AL161421.1.
- chr13:48,987,915–48,988,017, 1 gene: RNU6-60P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,099 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–45,895,970, 710 genes, copy number 5 (broad region; genes not listed).
- chr13:34,347,986–41,506,248, 109 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr16:3,953,387–8,299,772, 83 genes, copy number 5–7 (within-gene range 1–7) (broad region; genes not listed).
- chr16:11,547,722–18,598,328, 184 genes, copy number 7 (broad region; genes not listed).
- chr17:13,755,574–14,421,472, 13 genes, copy number 7 (within-gene range 1–7): COX10-AS1, AC005304.2, AC005304.1, AC005304.3, CDRT15P1, COX10, SNORA74, CDRT15, AC005224.1, HS3ST3B1, AC005224.3, AC005224.2, AC022816.1.

Autosomal genes at a single copy (total copy number 1): 15,016. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
